Somatic mutation profile of tumor specimen TCGA-A2-A0EX-01A (aliquot TCGA-A2-A0EX-01A-21W-A050-09) from TCGA case TCGA-A2-A0EX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 46.2 years (16,858 days).
Specimen TCGA-A2-A0EX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e26989c8-9a88-4696-bfaa-7b256e7e37c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0EX-10A (Blood Derived Normal), aliquot TCGA-A2-A0EX-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bfdb71b-1cc4-452b-8121-7c15d12dc578

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 38/108 reads (35%) | catalogued as rs1131690810, COSV55734715; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRG1 | c.1197C>A p.H399Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV65635925; called by muse, mutect2, varscan2
- AMIGO2 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs765326741, COSV99873407; called by muse, mutect2
- CALD1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.732); catalogued as COSV100723968; called by muse, mutect2
- EPB41L4A | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV54872422; called by muse, mutect2, varscan2
- FTSJ3 | c.2069A>G p.N690S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV63790460; called by muse, mutect2, varscan2
- FXYD5 | c.188G>A p.W63* | Nonsense Mutation (SNP) | VAF 39/182 reads (21%) | catalogued as COSV54343254; called by muse, mutect2, varscan2
- GRM1 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751529427, COSV51113828, COSV51116628, COSV99268846; called by muse, mutect2, varscan2
- HK1 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as COSV53860306; called by muse, mutect2, varscan2
- KRTAP3-2 | c.235A>T p.T79S | Missense Mutation (SNP) | VAF 92/286 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs1230080201, COSV66957156; called by muse, varscan2
- OR8U1 | c.531C>G p.F177L | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100163718, COSV56415682, COSV56419375; called by muse, mutect2
- PRDM16 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs768419281, COSV54586874; called by muse, mutect2, varscan2
- PRND | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.217); catalogued as COSV59896796; called by muse, mutect2, varscan2
- RESF1 | c.2311G>T p.V771F | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100440026; called by muse, mutect2
- RNF19A | c.254A>C p.N85T | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV61993704; called by muse, mutect2, varscan2
- SHE | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs781170865, COSV59072167; called by muse, mutect2, varscan2
- SNX3 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as rs1172338898, COSV57779084; called by muse, mutect2, varscan2
- ZNF223 | c.1347C>A p.N449K | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1003594545, COSV101398901; called by muse, mutect2, varscan2
- BTBD3 | c.1343G>A p.S448N | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA2013 | c.950del p.K317Rfs*32 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by mutect2, varscan2
- PPL | c.3422C>A p.A1141D | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.075); called by muse, mutect2
- ATP13A1 | c.2389C>A p.R797= | Silent (SNP) | VAF 2/12 reads (17%) | called by muse, mutect2
- NOL12 | c.447C>T p.P149= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs138812020; called by muse, mutect2
- PIKFYVE | c.5277C>T p.S1759= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV52243542; called by muse, mutect2
- PLEKHA4 | c.471C>T p.D157= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV54363948; called by muse, mutect2, varscan2
